Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A415, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A415-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of papillae having an fine fibrovascular stalk or colloid folliculae covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle or begnin tissue or muscle. The cells tend to maintain their polarity. Nuclei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is fibrous

Path Report: Tumor type: Papillary carcinoma

Tumor size: 1x0.7x0.7cm

Laterality: left

Tumor focality: Unifocal

Invasion of capsule: Yes

Extrathyroidal extension: No

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 7-20-12 RP

Source: NCI Genomic Data Commons file 9c19bb19-ba43-4623-a0fb-afcd774f4969 (TCGA-E8-A415.1592C973-2E73-4A7D-9DF3-7EFD67E67519.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).